TCGA case TCGA-CG-5726 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/863ad936-e2a0-471c-8d95-3a548bb94afa

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 73 years; Vital status: Dead; Days to death: 881 days (2.4 years).

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 73.9 years (26,998 days); Year of diagnosis: 2004; AJCC staging edition: 5th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 15.

Follow-up (1 entry)
- Days to follow up: 881 days (2.4 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-5726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-CG-5726-01A-01-TS1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 55.
  Slide TCGA-CG-5726-01A-01-BS1: Section location: Bottom; Percent tumor cells: 32; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 8; Percent stromal cells: 50.
- Sample TCGA-CG-5726-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-5726-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.5; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Hamburg; History reflux disease indicator: No; Antireflux treatment: Yes; History barretts esophageal indicator: No; Number of relatives with stomach cancer: 0.
- Antireflux treatment types: History reflux disease treatment: Proton Pump Inhibitors.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 881 days; disease-specific survival: no event (censored), 881 days; progression-free interval: no event (censored), 881 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CG-5726-01A-11D-1599-01): tumor purity 0.9, ploidy 2.18, whole-genome doublings 0.
